Somatic mutation profile of tumor specimen TCGA-D7-6520-01A (aliquot TCGA-D7-6520-01A-11D-1800-08) from TCGA case TCGA-D7-6520, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 53.3 years (19,467 days).
Specimen TCGA-D7-6520-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b04b9934-90ab-4dca-8594-d0cf6adc8f84.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-6520-10A (Blood Derived Normal), aliquot TCGA-D7-6520-10A-01D-1800-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/afc97d0a-0093-4e36-ad39-d1ac277d8025

The open-access MAF lists 65 somatic variants for this specimen: 47 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 39, Silent 18, Nonsense Mutation 4, Splice Site 2, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RHOA | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 39/78 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69041792, COSV69042056; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 20/43 reads (47%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCD3 | c.1426G>A p.G476S | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64642684; called by muse, mutect2, varscan2
- APOB | c.12452T>C p.L4151P | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51929714, COSV51950001; called by muse, mutect2, varscan2
- APOM | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762780216, COSV52989174; called by muse, mutect2, varscan2
- ATP5MF | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs771516671, COSV52854061; called by muse, mutect2, varscan2
- BRCA2 | c.2556C>G p.N852K | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as rs1566226932, COSV66448270, COSV66451177; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA2D4 | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755333586, COSV54947365; called by mutect2, varscan2
- CD300LF | c.21C>A p.Y7* | Nonsense Mutation (SNP) | VAF 13/45 reads (29%) | catalogued as COSV56896382, COSV56897641; called by muse, mutect2, varscan2
- CDH22 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs560457388, COSV64836997; called by muse, mutect2, varscan2
- CDHR1 | c.1275C>A p.N425K | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV60560859; called by muse, mutect2, varscan2
- CPEB4 | c.1526A>G p.K509R | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.149); catalogued as COSV54170790; called by muse, mutect2, varscan2
- CRISP2 | c.188G>A p.W63* | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as COSV59253904; called by muse, mutect2, varscan2
- DOCK10 | c.5998C>T p.R2000W | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs752843197, COSV51363981; called by muse, mutect2, varscan2
- DOCK10 | c.4786G>C p.E1596Q | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51364488; called by muse, mutect2, varscan2
- EPHA4 | c.1687C>T p.L563F | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV56029525; called by muse, mutect2, varscan2
- FLG2 | c.3139C>T p.Q1047* | Nonsense Mutation (SNP) | VAF 72/419 reads (17%) | catalogued as COSV66167535; called by muse, mutect2, varscan2
- GBF1 | c.1539G>C p.K513N (on ENST00000369983 / NM_001377137.1; = p.K512N on NM_004193.3) | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.94); catalogued as COSV100890720; called by muse, mutect2
- GCNT4 | c.606A>T p.R202S | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59280646; called by muse, mutect2, varscan2
- HNF4G | c.932T>A p.L311H (on ENST00000354370 / NM_001330561.2; = p.L358H on NM_004133.5) | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as COSV62966761; called by muse, mutect2, varscan2
- HRH2 | c.650A>G p.N217S | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs1382324716, COSV51573441; called by muse, mutect2, varscan2
- KCNH7 | c.3220G>T p.V1074L | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as COSV100149573, COSV59791808; called by muse, mutect2, varscan2
- KCNK13 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1175102644, COSV56411799; called by muse, mutect2, varscan2
- KRT73 | c.943C>T p.R315W | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs756808442, COSV59838517; called by muse, mutect2, varscan2
- OPHN1 | c.2185C>T p.R729W | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs1265135988, COSV62781341; called by muse, mutect2
- OR2AT4 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as COSV100532380, COSV59406706; called by muse, mutect2, varscan2
- OR2G2 | c.226T>G p.F76V | Missense Mutation (SNP) | VAF 58/216 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV60739912; called by muse, mutect2, varscan2
- OR6B1 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as rs371188814; called by muse, mutect2, varscan2
- PCDH17 | c.2236G>A p.E746K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.104); catalogued as rs1052450412, COSV64973008; called by muse, mutect2, varscan2
- PCDHGA8 | c.1603A>G p.S535G | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.158); catalogued as rs1220964310, COSV53920642; called by muse, mutect2, varscan2
- PIWIL1 | c.1019T>C p.V340A | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as rs1434623680, COSV55345318; called by muse, mutect2, varscan2
- POLR3B | c.815G>T p.C272F | Missense Mutation (SNP) | VAF 59/192 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV57277482; called by muse, mutect2, varscan2
- RABGGTB | c.660T>A p.C220* | Nonsense Mutation (SNP) | VAF 20/101 reads (20%) | catalogued as COSV54199833; called by muse, mutect2, varscan2
- RYR2 | c.857G>T p.G286V | Missense Mutation (SNP) | VAF 67/228 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV63675117; called by muse, mutect2, varscan2
- SERPINC1 | c.1214T>G p.L405R | Missense Mutation (SNP) | VAF 98/310 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62929104; called by muse, mutect2, varscan2
- SH3GL3 | c.586T>G p.L196V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.049); catalogued as COSV61054985; called by muse, mutect2, varscan2
- SLC22A1 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780454201, COSV61451950; called by muse, mutect2, varscan2
- SMR3B | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as rs1289351944, COSV59228664; called by muse, mutect2, varscan2
- TACC2 | c.244A>G p.K82E | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV57751166; called by muse, mutect2, varscan2
- TTN | c.63208G>A p.G21070S (on ENST00000591111; = p.G13646S on NM_003319.4) | Missense Mutation (SNP) | VAF 30/133 reads (23%) | PolyPhen probably damaging (0.999); catalogued as COSV59962102; called by muse, mutect2, varscan2
- USP26 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63708321; called by muse, mutect2, varscan2
- VPS36 | c.97-1G>C p.X33_splice | Splice Site (SNP) | VAF 17/64 reads (27%) | catalogued as COSV65198890; called by muse, mutect2, varscan2
- XIRP2 | c.10016C>G p.S3339C (on ENST00000628543; = p.S3514C on NM_152381.6) | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV54690736; called by muse, mutect2, varscan2
- ZNF268 | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.538); catalogued as COSV57212396; called by muse, mutect2
- COL5A3 | c.4726dup p.C1576Lfs*18 | Frame Shift Ins (INS) | VAF 14/32 reads (44%) | called by mutect2, pindel, varscan2
- RGS2 | c.274+2dup p.X92_splice | Splice Site (INS) | VAF 33/94 reads (35%) | called by mutect2, pindel, varscan2
- UMODL1 | c.214_255del p.K72_P85del | In Frame Del (DEL) | VAF 30/142 reads (21%) | called by mutect2, pindel
- CFAP58 | c.495C>A p.L165= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV57211696; called by muse, mutect2
- CTNND1 | c.1746T>A p.L582= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV62382683; called by muse, mutect2, varscan2
- DMD | c.4146C>T p.I1382= | Silent (SNP) | VAF 32/55 reads (58%) | catalogued as COSV63744034; called by muse, mutect2, varscan2
- EPHB2 | c.2238C>T p.D746= (on ENST00000400191 / NM_001309193.2; = p.D747= on NM_004442.7) | Silent (SNP) | VAF 51/160 reads (32%) | catalogued as COSV65861302; called by muse, mutect2, varscan2
- H1-5 | c.420G>A p.K140= | Silent (SNP) | VAF 50/216 reads (23%) | catalogued as COSV58899562; called by muse, mutect2, varscan2
- HDGFL1 | c.198C>T p.F66= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs921283671, COSV57751262; called by muse, mutect2, varscan2
- LRRC1 | c.243C>T p.F81= | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as COSV63823391; called by muse, mutect2, varscan2
- LRRC55 | c.894C>A p.I298= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV73006410; called by mutect2, varscan2
- NLRP12 | c.1182C>T p.N394= | Silent (SNP) | VAF 119/318 reads (37%) | catalogued as COSV60745412; called by muse, mutect2, varscan2
- OR2W3 | c.933A>G p.L311= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs1156309443, COSV64456487; called by muse, mutect2, varscan2
- OR52L1 | c.849T>C p.G283= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV59986408; called by muse, mutect2
- OTP | c.177C>T p.P59= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs760802561, COSV60568349, COSV60568686; called by muse, mutect2, varscan2
- RNLS | c.27C>T p.A9= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV59291922; called by muse, mutect2, varscan2
- ROBO3 | c.468C>T p.N156= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs766578334, COSV67300033; ClinVar: uncertain significance; called by muse, mutect2
- SLC35F3 | c.1158C>G p.L386= (on ENST00000366617 / NM_001300845.1; = p.L455= on NM_173508.4) | Silent (SNP) | VAF 37/107 reads (35%) | catalogued as COSV64018936; called by muse, mutect2, varscan2
- SOGA3 | c.1110C>T p.I370= | Silent (SNP) | VAF 47/90 reads (52%) | catalogued as rs765449375, COSV64105875; called by muse, mutect2, varscan2
- TATDN1 | c.234T>G p.P78= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV52678592; called by muse, mutect2, varscan2
- TMEM119 | c.423T>C p.S141= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV67188572; called by muse, mutect2, varscan2
